Somatic mutation profile of tumor specimen TCGA-G7-6793-01A (aliquot TCGA-G7-6793-01A-11D-1961-08) from TCGA case TCGA-G7-6793, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.8 years (22,215 days).
Specimen TCGA-G7-6793-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6db9f95c-0f30-4848-aedd-f01b3bb68a85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-6793-10A (Blood Derived Normal), aliquot TCGA-G7-6793-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d972829-eb46-40ee-8099-f11e2702e338

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 2, In Frame Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF6 | c.513T>A p.F171L | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51689741; called by muse, mutect2, varscan2
- CKAP2L | c.1073G>A p.S358N | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56696239; called by muse, mutect2, varscan2
- CNIH2 | c.87A>G p.I29M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV61012373; called by muse, mutect2, varscan2
- E4F1 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1369052123, COSV57038637; called by muse, mutect2, varscan2
- EXPH5 | c.5354G>A p.W1785* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as COSV56201285; called by muse, mutect2, varscan2
- ITGA4 | c.2942T>C p.I981T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV59206748; called by muse, mutect2, varscan2
- ITIH6 | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs781390419, COSV54488448; called by muse, mutect2, varscan2
- KRT6A | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV58104782; called by muse, mutect2, varscan2
- MED12 | c.3610G>T p.D1204Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61337565, COSV61342160; called by muse, mutect2, varscan2
- MOXD1 | c.685G>C p.G229R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60943693; called by muse, mutect2, varscan2
- N4BP2 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1351911905, COSV54701195; called by muse, mutect2, varscan2
- NBEAL1 | c.6892G>T p.D2298Y | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV58719742; called by muse, mutect2, varscan2
- PIK3CD | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV63128218; called by muse, mutect2, varscan2
- PRELP | c.1006C>A p.L336I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV58115680; called by muse, mutect2, varscan2
- RBBP7 | c.1101T>C p.F367= | Splice Region (SNP) | VAF 18/65 reads (28%) | catalogued as COSV58112800; called by muse, varscan2
- SLC9C1 | c.2404G>A p.A802T | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV59887592; called by muse, mutect2, varscan2
- SMG1 | c.6214A>G p.K2072E | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV67170805; called by muse, mutect2, varscan2
- SYT5 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV62830148; called by muse, mutect2, varscan2
- TAS1R2 | c.134T>A p.M45K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV64744553; called by muse, mutect2, varscan2
- USP25 | c.240C>G p.Y80* | Nonsense Mutation (SNP) | VAF 4/88 reads (5%) | catalogued as COSV53483558; called by muse, mutect2
- ZIK1 | c.801G>C p.W267C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV56736984; called by muse, mutect2, varscan2
- ZNF549 | c.1235C>G p.T412R (on ENST00000376233 / NM_001199295.2; = p.T399R on NM_153263.2) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53724847, COSV53728936; called by muse, mutect2, varscan2
- SPIDR | c.1232_1234dup p.S411dup | In Frame Ins (INS) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- CUBN | c.9141C>A p.I3047= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV64713998; called by muse, mutect2, varscan2
- ITGA8 | c.1119C>T p.D373= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV65227646; called by muse, mutect2, varscan2
- PDILT | c.1194C>T p.N398= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as rs755292330, COSV56701284; called by muse, mutect2, varscan2
- TTN | c.80670T>C p.Y26890= (on ENST00000591111; = p.Y19466= on NM_003319.4) | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV60002048; called by muse, mutect2, varscan2
- UBTD1 | c.195G>A p.K65= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV53968051; called by muse, mutect2, varscan2
- ATE1 | c.942+1005del | Intron (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
